Somatic mutation profile of tumor specimen TCGA-V1-A9OF-01A (aliquot TCGA-V1-A9OF-01A-11D-A41K-08) from TCGA case TCGA-V1-A9OF, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland.
Specimen TCGA-V1-A9OF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a23415c3-de95-4c0a-923e-30ba3f91a4d0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V1-A9OF-10A (Blood Derived Normal), aliquot TCGA-V1-A9OF-10A-01D-A41N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0b748f88-4ae7-4a96-a253-6f4fe696bd19

The open-access MAF lists 13 somatic variants for this specimen: 12 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 8, In Frame Del 1, Splice Site 1, Frame Shift Ins 1, Frame Shift Del 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SPOP | c.391T>G p.W131G | Missense Mutation (SNP) | VAF 61/172 reads (35%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.491); catalogued as rs1057519968, COSV61652911, COSV61653817; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BSN | c.6091C>T p.R2031C | Missense Mutation (SNP) | VAF 35/144 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.333); catalogued as rs759981264, COSV56522180; called by muse, mutect2, varscan2
- C2orf73 | c.527G>C p.R176T | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1166624021, COSV100471232; called by muse, mutect2, varscan2
- DDX41 | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 22/188 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as COSV100286407; called by muse, mutect2, varscan2
- ENTPD3 | c.1322A>C p.E441A | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV100088484; called by muse, mutect2, varscan2
- HNRNPH3 | c.857G>A p.G286E | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.166); catalogued as COSV99769144; called by muse, mutect2, varscan2
- PPRC1 | c.2819dup p.P941Tfs*75 | Frame Shift Ins (INS) | VAF 12/46 reads (26%) | catalogued as rs768056539; called by mutect2, varscan2
- SNW1 | c.1349C>G p.P450R | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99473097; called by muse, mutect2, varscan2
- TMEM131L | c.4042+1G>A p.X1348_splice | Splice Site (SNP) | VAF 5/19 reads (26%) | catalogued as rs1489410369, COSV99546907; called by muse, mutect2
- ZGPAT | c.746A>G p.K249R | Missense Mutation (SNP) | VAF 142/355 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV100203091; called by muse, mutect2, varscan2
- CDK12 | c.1047_1063del p.R350Qfs*3 | Frame Shift Del (DEL) | VAF 6/53 reads (11%) | called by mutect2, pindel
- MAP3K21 | c.835_837del p.D279del | In Frame Del (DEL) | VAF 15/47 reads (32%) | called by mutect2, pindel, varscan2
- MED13 | c.594A>G p.Q198= | Silent (SNP) | VAF 11/85 reads (13%) | catalogued as COSV100784893; called by muse, mutect2, varscan2
